Somatic mutation profile of tumor specimen BA2337D (aliquot aq-BA2337D) from BEATAML1.0 case 2312, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with t(8;21)(q22;q22), RUNX1-RUNX1T1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 53.3 years (19,465 days).
Specimen BA2337D: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f1d3c52a-82bc-4dec-8e0d-4b2f249e9798.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2058D (Solid Tissue Normal), aliquot aq-BA2058D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/34d25737-d813-4b29-9fb1-6174adc0ce30

The open-access MAF lists 14 somatic variants for this specimen: 10 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 7, Silent 4, Nonsense Mutation 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD18A | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs781203100, COSV101294900; called by muse, mutect2
- HAUS5 | c.1457C>T p.A486V | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as rs772550535; called by muse, varscan2
- LAMC3 | c.1985G>A p.G662E | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.111); catalogued as rs758415508; called by muse, mutect2, varscan2
- ZBTB7A | c.1195C>T p.R399* | Nonsense Mutation (SNP) | VAF 10/27 reads (37%) | catalogued as COSV59326485; called by muse, mutect2, varscan2
- CDH8 | c.1153G>T p.A385S | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2
- DLGAP2 | c.1145C>A p.A382D | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- KDM6A | c.460_461insTTGT p.Q154Lfs*8 | Frame Shift Ins (INS) | VAF 22/143 reads (15%) | called by mutect2, pindel, varscan2
- PDZD3 | c.1564G>A p.G522R (on ENST00000531114; = p.G442R on NM_024791.4) | Missense Mutation (SNP) | VAF 51/117 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- RPP40 | c.568G>T p.E190* | Nonsense Mutation (SNP) | VAF 4/56 reads (7%) | called by muse, mutect2
- TOR3A | c.916C>T p.L306F | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- FILIP1 | c.1140G>C p.V380= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as COSV52737026; called by muse, mutect2, varscan2
- KRT6C | c.1125C>T p.R375= | Silent (SNP) | VAF 79/307 reads (26%) | called by muse, mutect2, varscan2
- SLC12A5 | c.402C>A p.I134= (on ENST00000454036 / NM_001134771.2; = p.I111= on NM_020708.5) | Silent (SNP) | VAF 8/47 reads (17%) | called by muse, mutect2, varscan2
- WNT3 | c.963G>T p.T321= | Silent (SNP) | VAF 3/20 reads (15%) | catalogued as rs770999113; called by muse, mutect2
